Somatic mutation profile of tumor specimen TCGA-HE-7128-01A (aliquot TCGA-HE-7128-01A-11D-1961-08) from TCGA case TCGA-HE-7128, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-HE-7128-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 882b6f2e-c48b-4eba-bd8a-b33c549e5176.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HE-7128-10A (Blood Derived Normal), aliquot TCGA-HE-7128-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96781eb1-7635-4b10-aa56-ae68d885c772

The open-access MAF lists 41 somatic variants for this specimen: 35 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Frame Shift Del 6, Silent 5, In Frame Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL1 | c.3637T>C p.S1213P (on ENST00000340736 / NM_001008701.3; = p.S1208P on NM_014921.5) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61564921; called by muse, mutect2, varscan2
- ARHGEF17 | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); catalogued as COSV55233016; called by muse, mutect2, varscan2
- BTBD7 | c.1316T>G p.F439C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV58286445; called by muse, mutect2, varscan2
- CCDC88A | c.4879A>G p.S1627G (on ENST00000436346 / NM_001365480.1; = p.S1599G on NM_018084.5) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV55062525; called by muse, mutect2, varscan2
- DDI2 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.319); catalogued as rs773869764, COSV60779916; called by muse, mutect2, varscan2
- DMD | c.10951G>C p.D3651H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58914169; called by muse, mutect2, varscan2
- EPG5 | c.6923T>C p.L2308P | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56350550; called by muse, mutect2, varscan2
- FAM161A | c.464T>A p.M155K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV56766325; called by muse, mutect2
- KMT2D | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.102); catalogued as COSV56445616; called by mutect2, varscan2
- KMT2E | c.3257A>T p.D1086V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57573962; called by muse, mutect2, varscan2
- L3MBTL2 | c.1475A>G p.K492R | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.033); catalogued as COSV53433473, COSV53435446; called by muse, mutect2
- MAT2A | c.1019A>T p.K340M | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV52088511; called by mutect2, varscan2
- NDUFS3 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 79/349 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55454954; called by muse, mutect2, varscan2
- NR3C2 | c.2153C>G p.S718W | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV60991718; called by muse, mutect2, varscan2
- NRXN1 | c.4313G>C p.S1438T | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs1558506799, COSV60501006; called by muse, mutect2, varscan2
- NT5DC1 | c.207T>A p.D69E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60309165; called by muse, mutect2, varscan2
- OGFOD2 | c.964C>G p.R322G (on ENST00000228922 / NM_001304833.1; = p.R262G on NM_024623.3) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV54901551; called by muse, mutect2, varscan2
- OR6B2 | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV53154595; called by muse, mutect2, varscan2
- PHOSPHO2 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99775549; called by muse, mutect2, varscan2
- PIK3R6 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV61003471; called by muse, mutect2, varscan2
- PTPN11 | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV61009423; called by muse, mutect2, varscan2
- SGK1 | c.97A>G p.M33V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1240287713, COSV52809244; called by muse, mutect2, varscan2
- SREK1 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as rs868716407, COSV52333061; called by muse, mutect2, varscan2
- THAP9 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV56356581; called by muse, mutect2, varscan2
- TTC26 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1367130744, COSV58271681; called by muse, mutect2
- UTP20 | c.826A>G p.M276V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1441223197, COSV55378154; called by muse, mutect2, varscan2
- WDR92 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV54561647; called by muse, mutect2, varscan2
- CYP4F2 | c.488_491dup p.M164Ifs*7 | Frame Shift Ins (INS) | VAF 22/158 reads (14%) | called by mutect2, varscan2
- DZIP3 | c.27del p.F9Lfs*2 | Frame Shift Del (DEL) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- MIDN | c.1184_1186del p.L395del | In Frame Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- NOL11 | c.1019del p.G340Vfs*21 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, varscan2
- OASL | c.1178_1181del p.Q393Lfs*20 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel*, varscan2*
- OGN | c.659del p.L220Wfs*19 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- OR51A7 | c.378del p.H127Tfs*4 | Frame Shift Del (DEL) | VAF 13/105 reads (12%) | called by mutect2, pindel, varscan2
- PSMD1 | c.1118del p.N373Tfs*21 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- CACFD1 | c.393G>A p.T131= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs150411088; called by muse, mutect2, varscan2
- GPAT4 | c.441C>T p.S147= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV67840694; called by muse, mutect2, varscan2
- KCNQ2 | c.919C>T p.L307= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs1568927285, COSV60434627; called by muse, mutect2, varscan2
- MGME1 | c.309C>A p.I103= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV66624295; called by muse, mutect2, varscan2
- SLC27A2 | c.1862G>A p.*621= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV51059399; called by muse, mutect2, varscan2
- MROH8 | c.370+2459del | Intron (DEL) | VAF 5/20 reads (25%) | catalogued as rs1240061308; called by mutect2, pindel, varscan2
